Somatic mutation profile of tumor specimen TCGA-C5-A1BM-01A (aliquot TCGA-C5-A1BM-01A-11D-A13W-08) from TCGA case TCGA-C5-A1BM, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IB; Tumor grade: G2; Age at diagnosis: 78.9 years (28,815 days).
Specimen TCGA-C5-A1BM-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8029ceab-06fa-4e08-b3c9-774e2545e854.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-C5-A1BM-10A (Blood Derived Normal), aliquot TCGA-C5-A1BM-10A-01D-A13W-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/86e757e7-3ab8-4752-a8fd-b41b0e54f302

The open-access MAF lists 146 somatic variants for this specimen: 111 protein-altering or splice-affecting, 33 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 97, Silent 33, Nonsense Mutation 10, Splice Site 2, Intron 2, Frame Shift Ins 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1624G>A p.E542K | Missense Mutation (SNP) | VAF 16/89 reads (18%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.912); catalogued as rs121913273, CM153078, COSV55873227, COSV55894248; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PTEN | c.195C>G p.Y65* | Nonsense Mutation (SNP) | VAF 7/18 reads (39%) | hotspot (GDC flag); catalogued as rs878853936, CM110159, CM1513010, COSV64291341, COSV64293906; ClinVar: pathogenic; called by muse, mutect2
- AASDH | c.448G>A p.E150K | Missense Mutation (SNP) | VAF 28/95 reads (29%) | SIFT tolerated (0.17); PolyPhen benign (0.192); catalogued as COSV52707297; called by muse, mutect2, varscan2
- ANGPTL1 | c.1068C>G p.I356M | Missense Mutation (SNP) | VAF 32/152 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.948); catalogued as COSV52366747; called by muse, varscan2
- ANKAR | c.3145G>A p.E1049K | Missense Mutation (SNP) | VAF 37/130 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.025); catalogued as COSV99854162; called by muse, mutect2, varscan2
- ANPEP | c.920G>A p.S307N | Missense Mutation (SNP) | VAF 24/111 reads (22%) | SIFT tolerated (0.24); PolyPhen benign (0.013); catalogued as COSV55592135; called by muse, mutect2, varscan2
- APBB2 | c.1890G>C p.M630I (on ENST00000295974 / NM_001166050.2; = p.M631I on NM_004307.2) | Missense Mutation (SNP) | VAF 29/116 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as COSV55954296; called by muse, mutect2, varscan2
- APLF | c.1381G>C p.E461Q | Missense Mutation (SNP) | VAF 38/148 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.96); catalogued as rs1221229078, COSV58145348, COSV58147149; called by muse, mutect2, varscan2
- APOB | c.5098G>A p.D1700N | Missense Mutation (SNP) | VAF 40/165 reads (24%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as rs140783923, COSV51938953; called by muse, mutect2, varscan2
- ARHGAP35 | c.167C>T p.S56F | Missense Mutation (SNP) | VAF 23/103 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV68332037; called by muse, mutect2, varscan2
- ARHGAP36 | c.689C>T p.P230L | Missense Mutation (SNP) | VAF 28/85 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1220855026, COSV52263942, COSV99357184; called by muse, mutect2, varscan2
- ARHGAP6 | c.473C>T p.S158L | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.048); catalogued as COSV61629137; called by muse, mutect2, varscan2
- ASXL3 | c.3662C>G p.S1221C | Missense Mutation (SNP) | VAF 22/89 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs1245079335, COSV52468562; called by muse, mutect2, varscan2
- ATP2A2 | c.1886G>A p.G629D | Missense Mutation (SNP) | VAF 37/129 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV57875578; called by muse, mutect2, varscan2
- ATP2B4 | c.214G>C p.D72H | Missense Mutation (SNP) | VAF 12/135 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.812); catalogued as COSV100397435; called by muse, mutect2
- BAP1 | c.1379C>G p.S460* | Nonsense Mutation (SNP) | VAF 20/57 reads (35%) | catalogued as COSV56231488; called by muse, mutect2, varscan2
- BRMS1 | c.137C>G p.S46C | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as rs952363758, COSV60820232; called by muse, mutect2
- BTBD10 | c.541G>C p.D181H | Missense Mutation (SNP) | VAF 45/167 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs771981722, COSV53399560; called by muse, mutect2, varscan2
- C18orf21 | c.129T>G p.C43W | Missense Mutation (SNP) | VAF 43/153 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52449525; called by muse, mutect2, varscan2
- C19orf18 | c.373C>T p.R125* | Nonsense Mutation (SNP) | VAF 38/148 reads (26%) | catalogued as rs777382799, COSV58705218; called by muse, mutect2, varscan2
- C1orf112 | c.85G>A p.D29N | Missense Mutation (SNP) | VAF 26/114 reads (23%) | SIFT tolerated (0.53); PolyPhen benign (0.005); catalogued as COSV53679615; called by muse, mutect2, varscan2
- C5AR1 | c.443G>A p.R148Q | Missense Mutation (SNP) | VAF 33/106 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as rs757316710, COSV61892475; called by muse, mutect2, varscan2
- CC2D1A | c.2788G>A p.D930N | Missense Mutation (SNP) | VAF 31/132 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.147); catalogued as COSV54308880; called by muse, mutect2, varscan2
- CDK5RAP2 | c.658G>C p.D220H | Missense Mutation (SNP) | VAF 26/102 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs201528173, COSV62574991; called by muse, mutect2, varscan2
- CDR2 | c.574G>C p.E192Q | Missense Mutation (SNP) | VAF 48/171 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.787); catalogued as COSV51676486; called by muse, mutect2, varscan2
- CEP192 | c.6574C>T p.L2192F | Missense Mutation (SNP) | VAF 30/113 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as COSV58061364, COSV58065637; called by muse, varscan2
- COL22A1 | c.3862G>A p.G1288S | Missense Mutation (SNP) | VAF 28/118 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs769380944, COSV100277118, COSV57341198; called by muse, mutect2, varscan2
- CPSF4 | c.682C>T p.Q228* | Nonsense Mutation (SNP) | VAF 71/215 reads (33%) | catalogued as COSV52854834; called by muse, mutect2, varscan2
- CSTB | c.226G>A p.E76K | Missense Mutation (SNP) | VAF 29/128 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.132); catalogued as COSV52366958; called by muse, mutect2, varscan2
- CTAGE6 | c.764C>T p.A255V | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT tolerated (0.28); PolyPhen benign (0.017); catalogued as COSV69917222; called by mutect2, varscan2
- CYP2C9 | c.1070G>C p.R357T | Missense Mutation (SNP) | VAF 35/93 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53249645; called by muse, mutect2, varscan2
- DCHS1 | c.5284G>C p.E1762Q | Missense Mutation (SNP) | VAF 23/77 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55030899, COSV55035896; called by muse, mutect2, varscan2
- DDRGK1 | c.559G>A p.E187K | Missense Mutation (SNP) | VAF 18/96 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as COSV63226964; called by muse, mutect2, varscan2
- DEK | c.904G>C p.E302Q | Missense Mutation (SNP) | VAF 23/92 reads (25%) | SIFT tolerated (0.16); PolyPhen benign (0.432); catalogued as COSV55236610, COSV55238166; called by muse, mutect2
- DIRAS1 | c.373G>A p.E125K | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.78); catalogued as COSV60215843; called by muse, mutect2, varscan2
- E2F8 | c.1879G>C p.E627Q | Missense Mutation (SNP) | VAF 12/222 reads (5%) | SIFT tolerated (0.12); PolyPhen benign (0.203); catalogued as COSV100001456; called by muse, mutect2
- EGFR | c.2432C>G p.S811C | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs1378775962, COSV51777901, COSV51807983; called by muse, varscan2
- EVI2B | c.773G>A p.R258K | Missense Mutation (SNP) | VAF 35/149 reads (23%) | SIFT tolerated (0.16); PolyPhen benign (0.112); catalogued as COSV58364216, COSV58365301; called by muse, mutect2, varscan2
- FAM47A | c.1675G>A p.E559K | Missense Mutation (SNP) | VAF 29/94 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.066); catalogued as COSV60497516; called by muse, mutect2, varscan2
- FBXW8 | c.862G>A p.D288N (on ENST00000309909; = p.D326N on NM_012174.1) | Missense Mutation (SNP) | VAF 45/177 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV59300042; called by muse, mutect2, varscan2
- FIG4 | c.2008G>C p.E670Q | Missense Mutation (SNP) | VAF 6/104 reads (6%) | SIFT tolerated (0.49); PolyPhen benign (0.093); catalogued as COSV57791097; called by muse, mutect2
- FREM1 | c.3486G>C p.Q1162H | Missense Mutation (SNP) | VAF 45/166 reads (27%) | SIFT tolerated (0.17); PolyPhen benign (0.005); catalogued as COSV66524992; called by muse, mutect2, varscan2
- FRG1 | c.260-1del p.X87_splice | Splice Site (DEL) | VAF 4/24 reads (17%) | catalogued as rs1265231392; called by pindel, varscan2
- GABBR1 | c.123C>G p.I41M | Missense Mutation (SNP) | VAF 25/124 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV63542959; called by muse, mutect2, varscan2
- GLA | c.325G>C p.D109H | Missense Mutation (SNP) | VAF 63/211 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs869312277, COSV54508374, COSV54509443; called by muse, mutect2, varscan2
- GRAMD4 | c.981C>G p.F327L | Missense Mutation (SNP) | VAF 24/101 reads (24%) | SIFT tolerated (0.51); PolyPhen benign (0.287); catalogued as COSV63030723; called by muse, mutect2, varscan2
- GTSE1 | c.1649C>G p.P550R | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.527); catalogued as COSV71889215; called by muse, mutect2, varscan2
- H2AC8 | c.214C>G p.R72G | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV55126323, COSV99773208; called by muse, mutect2, varscan2
- HADH | c.56C>T p.S19L | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated (0.23); PolyPhen benign (0.015); catalogued as COSV58848576; called by muse, mutect2, varscan2
- HGSNAT | c.679C>T p.Q227* | Nonsense Mutation (SNP) | VAF 4/18 reads (22%) | catalogued as COSV65533732; called by muse, mutect2
- HIVEP1 | c.5349G>C p.L1783F | Missense Mutation (SNP) | VAF 67/204 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.73); catalogued as COSV65102338; called by muse, mutect2, varscan2
- HOXD9 | c.907G>C p.E303Q | Missense Mutation (SNP) | VAF 52/158 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50892276; called by muse, mutect2, varscan2
- IFT172 | c.4675A>G p.R1559G | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.39); catalogued as COSV51994499; called by muse, varscan2
- IGHMBP2 | c.2296G>A p.G766R | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs201989968, COSV54823128; called by muse, mutect2, varscan2
- KCNB2 | c.424C>T p.H142Y | Missense Mutation (SNP) | VAF 58/147 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.436); catalogued as COSV73050743; called by muse, mutect2, varscan2
- KCNJ8 | c.409G>T p.V137F | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53716743; called by muse, mutect2, varscan2
- KRBOX4 | c.504G>C p.K168N (on ENST00000344302 / NM_001129898.2; = p.K163N on NM_017776.2) | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.124); catalogued as COSV53343554; called by muse, mutect2, varscan2
- MAGEA12 | c.640G>A p.D214N | Missense Mutation (SNP) | VAF 65/273 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV63294846; called by muse, mutect2, varscan2
- MAPK11 | c.662C>T p.A221V | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT tolerated (0.49); PolyPhen benign (0.001); catalogued as COSV53133548; called by muse, mutect2, varscan2
- MAST4 | c.3781G>A p.E1261K (on ENST00000403625 / NM_001164664.2; = p.E1072K on NM_015183.3) | Missense Mutation (SNP) | VAF 40/136 reads (29%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); catalogued as rs765388394, COSV55128767, COSV55139642; called by muse, varscan2
- MBD6 | c.2363C>G p.S788* | Nonsense Mutation (SNP) | VAF 17/84 reads (20%) | catalogued as COSV63074969; called by muse, mutect2, varscan2
- MINAR1 | c.1841C>T p.S614L | Missense Mutation (SNP) | VAF 30/97 reads (31%) | SIFT tolerated (0.05); PolyPhen benign (0.01); catalogued as rs556179640, COSV59583636; called by muse, mutect2, varscan2
- MTOR | c.6571G>C p.D2191H | Missense Mutation (SNP) | VAF 31/108 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63872727, COSV63877620; called by muse, mutect2, varscan2
- MUC16 | c.19075G>C p.E6359Q | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.014); catalogued as COSV67472452; called by muse, mutect2, varscan2
- MYH11 | c.4808C>T p.T1603M | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.041); catalogued as rs376105806, COSV55551476; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NAA15 | c.449C>A p.S150* | Nonsense Mutation (SNP) | VAF 50/187 reads (27%) | catalogued as COSV56720287; called by muse, mutect2, varscan2
- NAV3 | c.2149T>C p.F717L | Missense Mutation (SNP) | VAF 33/127 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); catalogued as COSV57085638; called by muse, mutect2, varscan2
- NEDD4 | c.1834C>G p.L612V (on ENST00000508342 / NM_001284338.1; = p.L193V on NM_006154.4) | Missense Mutation (SNP) | VAF 46/137 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.842); catalogued as COSV59062768; called by muse, mutect2, varscan2
- OAS1 | c.663G>C p.K221N | Missense Mutation (SNP) | VAF 33/98 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.051); catalogued as COSV52536315; called by muse, mutect2, varscan2
- OR10A3 | c.591C>G p.I197M | Missense Mutation (SNP) | VAF 23/117 reads (20%) | SIFT tolerated (0.45); PolyPhen benign (0.16); catalogued as COSV62459199, COSV62459629; called by muse, mutect2, varscan2
- OR13C3 | c.869C>T p.A290V | Missense Mutation (SNP) | VAF 66/212 reads (31%) | SIFT tolerated (0.29); PolyPhen benign (0.036); catalogued as rs147645466; called by muse, mutect2, varscan2
- OR52N4 | c.908G>T p.R303L | Missense Mutation (SNP) | VAF 27/102 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.294); catalogued as COSV57891084, COSV57891432; called by muse, mutect2, varscan2
- OR8J1 | c.920C>A p.T307K | Missense Mutation (SNP) | VAF 31/111 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV57318707; called by muse, mutect2, varscan2
- P2RY13 | c.359C>T p.S120L | Missense Mutation (SNP) | VAF 24/124 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.732); catalogued as rs575804697, COSV56382105; called by muse, mutect2, varscan2
- PCNP | c.529G>C p.D177H | Missense Mutation (SNP) | VAF 27/131 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.22); catalogued as COSV54575045, COSV99504015; called by muse, mutect2, varscan2
- PDCD6IP | c.427G>A p.D143N | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.98); catalogued as COSV56243650; called by muse, mutect2, varscan2
- PDE1C | c.791C>G p.S264* | Nonsense Mutation (SNP) | VAF 32/117 reads (27%) | catalogued as COSV58516534; called by muse, mutect2, varscan2
- PDE3A | c.1568C>G p.S523* | Nonsense Mutation (SNP) | VAF 40/146 reads (27%) | catalogued as COSV100761761, COSV62974844; called by muse, mutect2, varscan2
- PDE4B | c.199G>C p.E67Q | Missense Mutation (SNP) | VAF 30/141 reads (21%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as COSV58480509; called by muse, mutect2, varscan2
- PDP2 | c.980C>T p.S327L | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.555); catalogued as rs1567517742, COSV61240726; called by muse, mutect2, varscan2
- PNPLA5 | c.866dup p.L290Pfs*19 | Frame Shift Ins (INS) | VAF 13/85 reads (15%) | catalogued as rs1332647081; called by mutect2, pindel, varscan2
- PPP1R3F | c.2185G>A p.E729K | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.003); catalogued as COSV50018712; called by muse, varscan2
- PTPRT | c.1180G>A p.E394K | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT tolerated (0.81); PolyPhen benign (0.067); catalogued as rs370385649; called by muse, mutect2, varscan2
- REG1A | c.326G>A p.R109H | Missense Mutation (SNP) | VAF 45/164 reads (27%) | SIFT tolerated (0.42); PolyPhen benign (0.001); catalogued as rs773643336, COSV52068747; called by muse, mutect2, varscan2
- ROCK1 | c.3511G>C p.D1171H | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV67696503; called by muse, mutect2, varscan2
- SAP130 | c.2053G>A p.E685K | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.655); catalogued as COSV52098397, COSV52099163; called by muse, mutect2, varscan2
- SCML2 | c.921G>C p.R307S | Missense Mutation (SNP) | VAF 72/316 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.101); catalogued as COSV52621990; called by muse, mutect2, varscan2
- SLC33A1 | c.769C>G p.L257V | Missense Mutation (SNP) | VAF 11/82 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as COSV100848350, COSV63947261; called by muse, varscan2
- SLC6A19 | c.927C>G p.I309M | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV58671902; called by muse, mutect2, varscan2
- SPTBN2 | c.5113G>A p.D1705N | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV59453675; called by muse, mutect2, varscan2
- SPTLC2 | c.1628G>A p.R543Q | Missense Mutation (SNP) | VAF 23/82 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.086); catalogued as rs763898397, COSV53638633, COSV53640695; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SRSF5 | c.38C>G p.P13R | Missense Mutation (SNP) | VAF 41/145 reads (28%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.739); catalogued as COSV67936894, COSV67937258; called by muse, mutect2, varscan2
- SYNGR4 | c.40G>A p.E14K | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.454); catalogued as rs201450222; called by muse, mutect2, varscan2
- TCF20 | c.809C>G p.S270C | Missense Mutation (SNP) | VAF 54/228 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV59492295; called by muse, mutect2, varscan2
- TIE1 | c.3005G>A p.R1002Q | Missense Mutation (SNP) | VAF 42/154 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV65248730; called by muse, mutect2, varscan2
- TNRC6A | c.416G>A p.R139Q | Missense Mutation (SNP) | VAF 40/150 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.037); catalogued as rs563907833, COSV59364711, COSV59366986; called by muse, mutect2, varscan2
- TONSL | c.3334C>A p.P1112T | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT tolerated (0.52); PolyPhen benign (0.193); catalogued as COSV68048488; called by muse, mutect2, varscan2
- TRIM39 | c.181G>C p.E61Q | Missense Mutation (SNP) | VAF 45/164 reads (27%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.678); catalogued as COSV100935918, COSV64955688; called by muse, mutect2, varscan2
- TSC2 | c.4998C>G p.F1666L | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV51918111, COSV51922542; called by muse, mutect2
- TTN | c.47301G>C p.K15767N (on ENST00000591111; = p.K8343N on NM_003319.4) | Missense Mutation (SNP) | VAF 21/84 reads (25%) | PolyPhen probably damaging (0.935); catalogued as COSV60119239; called by muse, mutect2, varscan2
- USP37 | c.2644-1G>A p.X882_splice | Splice Site (SNP) | VAF 9/23 reads (39%) | catalogued as COSV50285328, COSV50289495, COSV50290178; called by muse, mutect2, varscan2
- USP54 | c.4693C>T p.Q1565* | Nonsense Mutation (SNP) | VAF 86/214 reads (40%) | catalogued as COSV60443633; called by muse, mutect2, varscan2
- USP7 | c.121G>T p.V41L | Missense Mutation (SNP) | VAF 27/85 reads (32%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV61213413; called by muse, mutect2, varscan2
- USP9X | c.6331G>A p.E2111K | Missense Mutation (SNP) | VAF 78/273 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.743); catalogued as COSV61070021; called by muse, mutect2, varscan2
- ZNF320 | c.526C>T p.L176F | Missense Mutation (SNP) | VAF 16/93 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.286); catalogued as COSV67088285, COSV67088966; called by muse, mutect2, varscan2
- ZNF768 | c.1287C>G p.F429L | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.867); catalogued as COSV63322620; called by muse, mutect2, varscan2
- ZNF791 | c.1713G>C p.M571I | Missense Mutation (SNP) | VAF 38/106 reads (36%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as rs1409636344, COSV58480500; called by muse, mutect2, varscan2
- ZSWIM2 | c.1336C>G p.Q446E | Missense Mutation (SNP) | VAF 28/113 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV54576180; called by muse, mutect2, varscan2
- ABCC9 | c.3983_3990dup p.H1331Ffs*48 | Frame Shift Ins (INS) | VAF 22/114 reads (19%) | called by mutect2, varscan2
- KIR2DL3 | c.25G>A p.V9M | Missense Mutation (SNP) | VAF 14/98 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.139); called by muse, mutect2, varscan2
- PDE4DIP | c.2977C>T p.P993S | Missense Mutation (SNP) | VAF 24/157 reads (15%) | SIFT tolerated (0.7); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ABCA7 | c.5682G>C p.L1894= | Silent (SNP) | VAF 40/204 reads (20%) | catalogued as COSV99565662; called by muse, mutect2, varscan2
- ATOH1 | c.591A>G p.K197= | Silent (SNP) | VAF 12/56 reads (21%) | catalogued as rs773761668, COSV60038135; called by muse, varscan2
- C1orf56 | c.882C>T p.L294= | Silent (SNP) | VAF 35/187 reads (19%) | catalogued as rs752046535, COSV54846025, COSV54847775; called by muse, mutect2, varscan2
- CASP10 | c.1191C>T p.F397= (on ENST00000272879 / NM_032974.5; = p.F354= on NM_001230.5) | Silent (SNP) | VAF 18/90 reads (20%) | catalogued as rs769490565, COSV53778797; called by muse, mutect2, varscan2
- CLDN18 | c.66C>T p.I22= | Silent (SNP) | VAF 8/58 reads (14%) | catalogued as rs951589103, COSV51736732; called by mutect2, varscan2
- CLIP3 | c.1308G>A p.G436= | Silent (SNP) | VAF 39/104 reads (38%) | catalogued as COSV53324886; called by muse, mutect2, varscan2
- CUX1 | c.2172C>T p.L724= | Silent (SNP) | VAF 53/194 reads (27%) | catalogued as COSV52902609; called by muse, mutect2, varscan2
- DNAH17 | c.4827C>G p.L1609= | Silent (SNP) | VAF 12/45 reads (27%) | catalogued as rs1455825666, COSV67756347; called by muse, mutect2, varscan2
- DRD5 | c.726C>T p.I242= | Silent (SNP) | VAF 27/68 reads (40%) | catalogued as rs1487214163, COSV58578043; called by muse, mutect2, varscan2
- FBXW11 | c.1227C>T p.L409= | Silent (SNP) | VAF 19/105 reads (18%) | catalogued as COSV51609997, COSV99441332; called by muse, mutect2, varscan2
- GFPT1 | c.2004G>A p.V668= (on ENST00000357308 / NM_001244710.2; = p.V650= on NM_002056.4) | Silent (SNP) | VAF 24/98 reads (24%) | catalogued as COSV61948440; called by muse, mutect2, varscan2
- GGN | c.1608C>T p.G536= | Silent (SNP) | VAF 9/37 reads (24%) | catalogued as COSV99287444; called by muse, mutect2, varscan2
- ITGA1 | c.1782G>C p.P594= | Silent (SNP) | VAF 26/87 reads (30%) | catalogued as COSV50884464; called by muse, mutect2, varscan2
- KMT2D | c.10893C>G p.L3631= | Silent (SNP) | VAF 6/22 reads (27%) | catalogued as COSV56449982; called by muse, mutect2
- LCOR | c.606C>T p.F202= | Silent (SNP) | VAF 26/62 reads (42%) | catalogued as COSV63631179; called by muse, mutect2, varscan2
- LVRN | c.2721C>T p.D907= | Silent (SNP) | VAF 22/83 reads (27%) | catalogued as COSV63497453; called by muse, mutect2, varscan2
- NTNG1 | c.945C>T p.C315= | Silent (SNP) | VAF 124/291 reads (43%) | catalogued as rs1432684136, COSV53967422; called by muse, mutect2, varscan2
- PI4KA | c.327A>G p.K109= | Silent (SNP) | VAF 79/233 reads (34%) | catalogued as COSV55413423; called by muse, mutect2, varscan2
- PIGK | c.9C>T p.V3= | Silent (SNP) | VAF 10/40 reads (25%) | catalogued as rs1308694813, COSV63062358; called by muse, mutect2, varscan2
- RACGAP1 | c.1898G>A p.*633= | Silent (SNP) | VAF 39/123 reads (32%) | catalogued as COSV56699549; called by muse, mutect2, varscan2
- RBM19 | c.1263C>T p.L421= | Silent (SNP) | VAF 16/78 reads (21%) | catalogued as COSV99925968; called by muse, mutect2, varscan2
- RNF214 | c.1083G>A p.E361= | Silent (SNP) | VAF 39/109 reads (36%) | catalogued as rs757962514, COSV56119314; called by muse, mutect2, varscan2
- RNF4 | c.288C>T p.D96= | Silent (SNP) | VAF 5/22 reads (23%) | catalogued as rs749452553, COSV58643094; called by muse, mutect2
- RTF1 | c.1551G>A p.L517= | Silent (SNP) | VAF 29/93 reads (31%) | catalogued as COSV67478257; called by muse, mutect2, varscan2
- SCN4A | c.4053G>A p.T1351= | Silent (SNP) | VAF 33/150 reads (22%) | catalogued as rs376395544; called by muse, mutect2, varscan2
- SCN8A | c.3732C>A p.I1244= | Silent (SNP) | VAF 53/185 reads (29%) | catalogued as COSV100633227, COSV61983569; called by muse, varscan2
- SEMA3D | c.66G>A p.L22= | Silent (SNP) | VAF 21/70 reads (30%) | catalogued as COSV52395832; called by muse, mutect2, varscan2
- SGPP2 | c.948C>G p.L316= | Silent (SNP) | VAF 28/98 reads (29%) | catalogued as COSV58329526; called by muse, mutect2
- SNRNP200 | c.81C>T p.L27= | Silent (SNP) | VAF 18/62 reads (29%) | catalogued as COSV60490570; called by muse, varscan2
- SNRPD1 | c.9C>G p.L3= | Silent (SNP) | VAF 97/389 reads (25%) | catalogued as rs139445414, COSV55932899; called by muse, mutect2, varscan2
- TTLL12 | c.1635G>A p.T545= | Silent (SNP) | VAF 5/27 reads (19%) | catalogued as rs199507307, COSV53354818; called by muse, mutect2, varscan2
- TTYH2 | c.906G>A p.Q302= | Silent (SNP) | VAF 46/185 reads (25%) | catalogued as COSV99483001; called by muse, mutect2, varscan2
- WDR35 | c.9C>T p.F3= | Silent (SNP) | VAF 5/19 reads (26%) | catalogued as COSV55603762; called by muse, mutect2, varscan2
- DPP6 | c.627+21098C>G | Intron (SNP) | VAF 23/90 reads (26%) | catalogued as COSV59619827; called by muse, mutect2, varscan2
- MARK4 | c.1877+241G>A | Intron (SNP) | VAF 24/77 reads (31%) | catalogued as rs767049510, COSV53464930; called by muse, mutect2, varscan2
